Surgical pathology report (de-identified scan), TCGA case TCGA-FY-A40N, project TCGA-THCA (Thyroid Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-FY-A40N-01A (Primary Tumor).

[page 1 of 2]
Referring Physician:

DOB: Age Gender

Ref#: Hosp#: Provider Group:

Date of Service: Date Received: Outpatient
Room: Bed: Date Reported:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. - D.) THYROID, MEDIASTINAL LYMPH NODES, PARTIAL THYROIDECTOMY FOLLOWED BY TOTAL THYROIDECTOMY AND LYMPH NODE DISSECTION:

- Papillary thyroid carcinoma.
- Multifocal, 0.9 and 0.5 cm in greatest dimension.
- Limited to thyroid.
- Surgical margins negative.
- Three lymph nodes, no tumor seen (0/3).

ICD-O-3
Carcinoma, papillary,
follicular variant
8340/3
Site: thyroid, NOS
C73.9
7-3-12
R0

PATHOLOGIC TUMOR STAGING SYNOPSIS (THYROID):

Type and Grade: Papillary thyroid carcinoma.

Primary tumor: pT1a.

Regional lymph nodes: pN0.

Distant metastasis: N/A.

Pathologic stage: I.

Lymphovascular invasion: Not identified.

Margin status: R0, negative.

Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th ed, and CAP protocol.

IHPAA Discrepancy		
Case Ineligible		
Review Initiated		

Case #:

Printed:

Phone:

Page 1

This report continues... (FINAL)

[page 2 of 2]
Case #:

FINAL SURGICAL PATHOLOGY REPORT

Signed by

Source of Specimen:

- A. Thyroid isthmus
- B. Right lobe of thyroid
- C. Left lobe of thyroid
- D. Mediastinal central nodes

Clinical History/Operative Dx:

Thyroid mass

Intraoperative Diagnosis:

- A. TP/FSA: Thyroid isthmus: Positive for papillary carcinoma. (Dr. [redacted])
The intraoperative interpretation(s) was/were performed and rendered at [redacted]

Gross Description:

A. The specimen is labeled thyroid isthmus and is received without fixative. It consists of a 1.4 x 0.9 x 0.9 cm rounded red firm nodule. The external surface is inked black. The specimen is serially sectioned and touch imprints are obtained. Representative tissue is submitted for frozen section. Representative tissue is obtained for research purposes. The tissue remaining from frozen section is submitted for permanent section in A1. The remaining tissue is submitted in cassette A2. (

B. The specimen is labeled right lobe of thyroid and is received in formalin. It consists of an ovoid fragment of firm red tissue which weighs 3 grams. It measures 3 x 1.8 x 0.8 cm. Orientation is not obvious and the external surface is inked black. There are no grossly identifiable parathyroid glands. The specimen is serially sectioned and sequentially and entirely submitted in cassettes B1-B4. (

C. The specimen is labeled left lobe of thyroid and is received in formalin. It consists of a thyroid lobe which weighs 5 grams and measures 3.5 cm from superior to inferior, 2.4 cm from medial to lateral, and 0.9 cm from anterior to posterior. There are no grossly obvious parathyroid glands. The anterior surface is inked green and the posterior surface is inked black. The specimen is serially sectioned and sequentially and entirely submitted from superior to inferior in cassettes C1-C5. (

D. The specimen is labeled mediastinal central nodes and is received in formalin. It consists of three fragments of pale yellow-tan tissue, with the largest fragment measuring 1 x 0.5 x 0.4 cm and two smaller fragments each 0.5 cm in maximum dimension. The larger specimen is inked. The specimen is trisected and combined with the remaining two fragments in cassette D1. (

Microscopic Description:

- A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Case #: 5

Printed:

Page 3

This report continues... (FINAL)

Source: NCI Genomic Data Commons file 9fce5a1b-aed4-43e8-b29b-e99274da922b (TCGA-FY-A40N.A3902FF5-8B0C-4239-BE35-F9832C38A8FD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).